Surgical pathology report (de-identified scan), TCGA case TCGA-BC-A10Q, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UNC, specimen TCGA-BC-A10Q-01A (Primary Tumor).

SURGICAL PATHOLOGY

Case Number :

Collection Date :

CLINICAL INFORMATION

The patient is with **hepatocellular carcinoma** by fine needle aspiration. She undergoes extended left hemihepatectomy and cholecystectomy.

GROSS DESCRIPTIONS

Received are two formalin-filled containers each labeled with the patient's name and MR#.

Container #1 holds a fresh liver resection specimen. The specimen was received by the frozen section team and a portion of tumor was given to tissue procurement and a portion of uninvolved liver was also submitted for research. The specimen weighs 630 grams and measures 16 x 13.5 x 5.5 cm. It includes the left lobe and a portion of the right lobe. The tumor measures 10 x 9 x 7 cm. In the region of the tumor, the capsule of the

liver is white and firm with central puckering. The tumor extends 2 cm to the left of the calciform ligament and 8 cm to the right. It approaches the resection margin in multiple areas superiorly and the right end of the specimen. On cut section the tumor is firm with a fairly homogenous yellow-tan appearance. The tumor is well circumscribed. The uninvolved liver parenchyma and capsule are grossly unremarkable. Sections are

submitted as per block summary.

Container #2 is additionally labeled "gallbladder". It holds a gallbladder measuring 7 x 2.5 x 2 cm. The external surface shows a few scattered petechiae. The lumen is filled with dark green bile. The mucosa is green and velvety. No stones are identified. Wall thickness is 1 mm. Representative sections are submitted in block 12.

1CD-0-3

BLOCK SUMMARY

- 1&2 - tumor and superior margin
- 3&4 - tumor and right resection margins
- 5 - central tumor
- 6 - tumor and anterior capsule
- 7 - additional central tumor
- 8 - tumor with vessel
- 9 - tumor with posterior capsule and tumor liver interface
- 10&11 - uninvolved liver
- 12 - gallbladder

carcinoma, hepatocellular, Nos 8170/3
Site: liver C22-0
w 7/5/11

LIGHT MICROSCOPY

Light microscopic examination is performed.

DIAGNOSIS

LIVER, PARTIAL HEPATECTOMY - **HEPATOCELLULAR CARCINOMA**, MIXED SCLEROSING AND ADENOID PATTERNS WITH MULTIFOCAL EXTENSION TO SURGICAL MARGINS

- NO VASCULAR SPACE INVASION IDENTIFIED

GALLBLADDER, TOTAL REMOVAL - NO PATHOLOGIC ABNORMALITY

Source: NCI Genomic Data Commons file 389f6219-6b03-4e41-ae45-86f60e4bdccf (TCGA-BC-A10Q.10117C34-85C2-49DE-B2AD-F8D0D4570DA9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).